Somatic mutation profile of tumor specimen MP2PRT-PAPFHY-TBP1-A (aliquot MP2PRT-PAPFHY-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFHY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (940 days).
Specimen MP2PRT-PAPFHY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 666a4782-d2e5-46be-9030-89f6a56e0af2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFHY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFHY-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6fee162-d5a7-4cce-838a-a6bd79707cc2

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); catalogued as rs200540199, COSV53025304; called by muse, mutect2, varscan2
- PRAG1 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 224/719 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs201115647; called by muse, mutect2, varscan2
- GABRB3 | c.243T>C p.D81= | Splice Region (SNP) | VAF 97/193 reads (50%) | called by muse, mutect2, varscan2
- PTX3 | c.488T>A p.L163Q | Missense Mutation (SNP) | VAF 288/565 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TTC6 | c.1323T>A p.N441K (on ENST00000267368; = p.N1807K on NM_001310135.3) | Missense Mutation (SNP) | VAF 21/535 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- MINK1 | c.156C>T p.A52= | Silent (SNP) | VAF 45/294 reads (15%) | catalogued as rs1290705644; called by muse, mutect2, varscan2
- RSPH6A | c.1236C>T p.P412= | Silent (SNP) | VAF 241/548 reads (44%) | catalogued as rs773950083, COSV55574742; called by muse, mutect2, varscan2
